Surgical pathology report (de-identified scan), TCGA case TCGA-44-6778, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6778-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Date Recd: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Lingula
- B. Level 10 lymph node
- C. Level 7 lymph node
- D. Level 5 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass.

GROSS DESCRIPTION

A. Part A is submitted fresh for tissue procurement, labeled "lingula". It consists of an elongated portion of lung tissue, measuring 18 x 4 x 2 cm. maximally. It has been amputated along an entire edge, which has steel clips and paper tape present. There is an area of pleural puckering opposite the tape, which has drawn the pleura into a stellate-like area, with a palpable mass deep to that. The pleura is focally torn along another portion of the specimen. Black ink is applied over the area of the scar and then the specimen is serially sectioned. This reveals the presence of a nodular tumor mass immediately beneath the pleura, in the region of the above-mentioned scar. That tumor mass measures maximally 2 x 1.5 x 1.3 cm. Sections through the remaining pulmonary parenchyma reveal a consolidated bloody red tissue, without other focal nodules present. There is some adherent fat present on the pleural surface. Representative tumor and normal [REDACTED] ions are submitted for tissue procurement, per request of [REDACTED]. Sections after fixation.

Part B is submitted fresh, labeled "Level 10 lymph node". It consists of multiple black and red tissue portions. Three are present, each measuring 6 to 8 mm. in greatest extent. AS-1

C. Part C is submitted fresh, labeled "Level 7 lymph node". It consists of a single 7 mm. fragment of black and red tissue. AS-1

D. Part D is submitted fresh, labeled "Level 5 lymph node". It consists of two portions of fatty red and black with an aggregate dimension of 1 cm. AS-1

[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.
Histologic grade: Moderate to poorly differentiated.
Primary tumor (pT): Tumor measures 2 x 1.5 x 1.3 cm and does not involve the visceral pleural surface (pT1).
Margins of resection: Negative.
Direct extension of tumor: Absent.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Negative.
Regional lymph nodes (pN): The level 5, 7, and 10 mediastinal nodes are negative for metastatic carcinoma (pN0).
Distant metastasis (pM): Cannot be assessed (pMX).

[page 2 of 2]
[REDACTED]

Other findings: Emphysematous bullae. Pleural based fibrous scar with old hemorrhage.

4, 3x3

DIAGNOSIS

- A. Lung, lingula, wedge resection:
- Invasive moderate to poorly differentiated adenocarcinoma.
- The visceral pleural surface and margin of resection are free of tumor. Emphysematous bullae.
- Pleural based fibrous scar with old hemorrhage.
- B. Lymph node, level 10, resection:
- Negative for metastatic carcinoma.
- C. Lymph node, level 7, resection:
- Negative for metastatic carcinoma.
- D. Lymph node, level 5, resection:
- Negative for metastatic carcinoma.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file aa0f81ee-6f4a-48fa-afcc-4f309680c514 (TCGA-44-6778.B1F41C0E-A2A1-4945-85B3-A2EF6A994CBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).